Surgical pathology report (de-identified scan), TCGA case TCGA-61-2113, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2113-01A (Primary Tumor).

FINAL DIAGNOSIS:

FINAL DIAGNOSIS:

-
- RIGHT OVARY:
- ADENOCARCINOMA, MODERATELY TO POORLY DIFFERENTIATED, MIXED PAPILLARY AND ENDOMETRIOID TYPE, AND EXTENSIVE LYMPHOVASCULAR PERMEATION
- RIGHT FALLOPIAN TUBE WITH NO SPECIFIC PATHOLOGIC CHANGE
- B) UTERUS, 75 GRAMS, AND LEFT ADNEXA:
- CHRONIC CERVICITIS WITH SQUAMOUS METAPLASIA
- PROLIFERATIVE PATTERN ENDOMETRIUM
- METASTATIC OVARIAN ADENOCARCINOMA INVOLVING THE SEROSAL SURFACE
- LEFT OVARY AND FALLOPIAN TUBE WITH NO SPECIFIC PATHOLOGIC CHANGE
- C) RIGHT PELVIC LYMPH NODES:
- FOUR LYMPH NODES, POSITIVE FOR TUMOR (4/4)
- D) APPENDIX:
- ADENOCARCINOID TUMOR, TUBULAR TYPE
- E) OMENTUM:
- NEGATIVE FOR TUMOR
- F) SMALL BOWEL:
- NEGATIVE FOR TUMOR

Source: NCI Genomic Data Commons file 8167705f-dc57-44e6-ac51-6faff0154db3 (TCGA-61-2113.D10E1B61-73C4-4AB7-BC4B-8C7827856602.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).